Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A896, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A896-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with left renal mass

Research Dx

Left kidney, radical nephrectomy:

Papillary renal cell carcinoma.

Please see case summary.

ICD-O.3
Carcinoma, papillary renal
carcinoma 8260/3
Site D Kidney NOS 864.9
9/11/22/13

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Radical nephrectomy

Specimen laterality: Left

Tumor site: Middle

Tumor size: 6 cm

Extent of disease: Tumor extension into renal sinus

Histologic type: Papillary renal cell carcinoma

Sarcomatoid features: Present, 10%

Tumor necrosis: Present

Histologic grade (Fuhrman Nuclear Grade): 4

Margins: Negative

Lymphovascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT3a (tumor invades renal sinus fat but not beyond Gerota's fascia)

Regional lymph nodes: No lymph nodes submitted

Number examined: 0

Number involved: Not applicable

Distant metastasis: pM-not applicable

Pathologic findings in nonneoplastic kidney: Peritumoral interstitial chronic inflammation and sclerosed glomeruli; arteriolonephrosclerosis

Other tumors and/or tumor-like lesions: Small renal cyst; negative adrenal gland

AJCC Staging (7th edition) pT3a pNX pM-not applicable

QC

Research QC

Tumor:

95% tumor nuclei

0% necrosis

5% normal

Normal:

100% kidney and adipose

Research Specimen

—

Specimen Process Time

Plasma/serum/buffy coat

Cold ischemia start time:

[page 2 of 2]
Plasma frozen @
Serum frozen @
Buffy coat frozen @

Tissue:

Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time:
Formalin fixation stop time
Total formalin fixation time:

Specimen Weight

Normal

1- 290 mg, 520 mg, 3- 300 mg, 4- 320 mg

Tumor

1- 650 mg, 2- 600 mg, 3- 690 mg, 4- 890 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 8

Normal x 4

Tumor x 4

Metastatic - N/A

FFPE x 8

Normal x 4

Tumor x 4

Metastatic - N/A

Study

Patient Consent

Yes

Criteria	met 10/24/13	No
IPSA Discrepancy		

Source: NCI Genomic Data Commons file d0c8b27e-7a59-435e-86bf-dd02d30ffe01 (TCGA-Y8-A896.870F0307-FD8D-4ADB-82EC-118A27D591B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).